Somatic mutation profile of tumor specimen TCGA-49-6767-01A (aliquot TCGA-49-6767-01A-11D-1855-08) from TCGA case TCGA-49-6767, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.8 years (17,108 days).
Specimen TCGA-49-6767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c07a24a8-cdb2-4ae2-af2c-33848f15159f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-6767-11A (Solid Tissue Normal), aliquot TCGA-49-6767-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06ce81ad-a9fd-4f9c-9c7e-1ddbd8ec9d29

The open-access MAF lists 519 somatic variants for this specimen: 374 protein-altering or splice-affecting, 127 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 315, Silent 127, Nonsense Mutation 28, Splice Site 11, Intron 9, Frame Shift Del 9, Frame Shift Ins 5, RNA 3, 5'UTR 3, Splice Region 3, Translation Start Site 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5839G>T p.E1947* (on ENST00000358273 / NM_001042492.3; = p.E1926* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as rs587782088, COSV62206987; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ABCA10 | c.677C>A p.A226E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV52223890; called by muse, mutect2
- ABCA13 | c.12022C>A p.P4008T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV71289741; called by muse, mutect2, varscan2
- ABCB5 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.159); catalogued as rs981749265, COSV99327854; called by muse, mutect2, varscan2
- ABCB7 | c.1323G>A p.M441I (on ENST00000373394 / NM_001271696.3; = p.M442I on NM_004299.6) | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV53720621, COSV53722985; called by muse, mutect2
- ABHD10 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.783); catalogued as COSV56325362; called by muse, mutect2, varscan2
- ABHD13 | c.322G>T p.G108* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV101024104; called by muse, mutect2, varscan2
- ACSL1 | c.1819A>G p.T607A | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55663561; called by muse, mutect2
- ACSL4 | c.1392G>T p.Q464H (on ENST00000340800 / NM_022977.2; = p.Q423H on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868773655, COSV61614815; called by muse, mutect2
- ACTL7B | c.661C>A p.R221S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV101012561, COSV65927559; called by muse, mutect2, varscan2
- ADAM23 | c.1627G>T p.G543W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407664125, COSV52218231; called by muse, mutect2, varscan2
- ADAMTS15 | c.2331G>T p.E777D | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353997466, COSV54506449; called by muse, mutect2, varscan2
- ADAMTS6 | c.1371-1G>T p.X457_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as COSV66860959; called by muse, mutect2, varscan2
- ADGRG4 | c.2969T>C p.L990S | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV54958567; called by muse, mutect2
- AFF2 | c.3558G>T p.M1186I | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.825); catalogued as COSV53993461; called by mutect2, varscan2
- AGL | c.4404G>T p.L1468F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.398); catalogued as COSV54047549, COSV54053780; called by muse, mutect2, varscan2
- AHNAK2 | c.8621C>A p.A2874D | Missense Mutation (SNP) | VAF 69/382 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV60918337; called by muse, mutect2, varscan2
- AHNAK2 | c.1140G>T p.R380S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV60918351; called by muse, mutect2, varscan2
- AKAP6 | c.4352C>T p.P1451L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV55217271; called by muse, mutect2, varscan2
- AKNA | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV56313244; called by muse, mutect2, varscan2
- ALCAM | c.1241-1G>T p.X414_splice | Splice Site (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100064510; called by mutect2, varscan2
- ALCAM | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100064519; called by mutect2, varscan2
- AMER1 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as COSV100365662, COSV57662113; called by muse, mutect2
- ANK1 | c.5110G>T p.D1704Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV55884272; called by muse, mutect2, varscan2
- ANKRD13B | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV101198880; called by muse, mutect2, varscan2
- ANKRD34B | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1457244402, COSV58614066; called by muse, mutect2
- ANKRD45 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV60961469; called by muse, mutect2, varscan2
- ARAP2 | c.3018T>A p.F1006L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV58288032; called by muse, mutect2, varscan2
- ARHGAP10 | c.312+1G>T p.X104_splice | Splice Site (SNP) | VAF 16/57 reads (28%) | catalogued as COSV60600869; called by muse, mutect2, varscan2
- ARHGAP36 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.313); catalogued as rs759849724, COSV52268022, COSV99357196; called by muse, mutect2
- ARHGAP6 | c.1078-2A>G p.X360_splice | Splice Site (SNP) | VAF 9/136 reads (7%) | catalogued as COSV57297372; called by muse, mutect2
- ARMCX5 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as COSV55766837; called by muse, mutect2
- ARMCX5-GPRASP2 | c.686C>G p.A229G | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV63438209, COSV63439317; called by muse, varscan2
- ATP7A | c.1903G>T p.D635Y | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM131217, COSV58447846; called by muse, mutect2
- ATRX | c.3667G>C p.E1223Q | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as COSV64878137, COSV64881096; called by muse, mutect2
- BCKDHB | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM062457, COSV100243380; called by muse, mutect2, varscan2
- BTN3A1 | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1561850520, COSV50024932; called by muse, mutect2, varscan2
- BTNL8 | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV51459362; called by muse, mutect2, varscan2
- C1GALT1C1 | c.957A>T p.*319Cext*53 | Nonstop Mutation (SNP) | VAF 41/86 reads (48%) | catalogued as COSV100485591; called by muse, mutect2, varscan2
- C2orf80 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as rs769113460, COSV58016193, COSV58017227; called by muse, mutect2, varscan2
- C8A | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.253); catalogued as COSV63483967, COSV63484790; called by muse, mutect2, varscan2
- C8B | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.162); catalogued as COSV64778100; called by muse, mutect2, varscan2
- CALN1 | c.17T>A p.V6E (on ENST00000329008 / NM_001017440.3; = p.V48E on NM_031468.4) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61137155; called by muse, mutect2, varscan2
- CAVIN2 | c.798G>C p.E266D | Missense Mutation (SNP) | VAF 116/333 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58424565; called by muse, mutect2, varscan2
- CBLL1 | c.1397T>C p.L466S | Missense Mutation (SNP) | VAF 98/362 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56029447; called by muse, mutect2, varscan2
- CCDC61 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs377508784, COSV54428985; called by muse, mutect2, varscan2
- CCN4 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as COSV51531200; called by muse, mutect2, varscan2
- CD163L1 | c.2288A>G p.E763G | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58017948; called by muse, mutect2, varscan2
- CD1D | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV63809212; called by muse, mutect2, varscan2
- CD248 | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140616335; called by muse, mutect2, varscan2
- CD6 | c.1457A>T p.Y486F | Missense Mutation (SNP) | VAF 120/193 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV57839579; called by muse, mutect2, varscan2
- CD93 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs761695801, COSV55663392; called by muse, mutect2, varscan2
- CD99L2 | c.506G>C p.R169P | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV60936782; called by muse, mutect2, varscan2
- CDH12 | c.1354A>C p.T452P | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.21); catalogued as COSV66413465; called by muse, mutect2, varscan2
- CDH2 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749639068, COSV52283518; called by muse, mutect2, varscan2
- CEL | c.2223dup p.T742Hfs*3 (on ENST00000673714; = p.T739Hfs*3 on NM_001807.6) | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | catalogued as rs747827877; called by pindel, varscan2
- CHORDC1 | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57706295; called by muse, mutect2, varscan2
- CHRNA4 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV64719848; called by muse, mutect2, varscan2
- CLEC18B | c.932T>G p.F311C | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100375824; called by muse, mutect2
- CLNK | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV57016105, COSV57016480; called by muse, mutect2, varscan2
- CNTNAP4 | c.1881C>A p.T627= | Splice Region (SNP) | VAF 22/132 reads (17%) | catalogued as COSV100269834, COSV56685383; called by muse, mutect2
- COL11A1 | c.1630-1G>T p.X544_splice | Splice Site (SNP) | VAF 8/69 reads (12%) | catalogued as COSV62185523, COSV62186144; called by muse, mutect2, varscan2
- COL12A1 | c.2915G>T p.R972I | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as COSV59398031; called by muse, mutect2, varscan2
- COL17A1 | c.3623C>T p.A1208V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100793102; called by muse, mutect2, varscan2
- COL17A1 | c.3622G>T p.A1208S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV100793103; called by muse, mutect2, varscan2
- COL3A1 | c.910G>C p.A304P | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs756075915, COSV58590387; called by muse, mutect2, varscan2
- CPSF1 | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs576268637, COSV58232592; called by muse, mutect2, varscan2
- CPXCR1 | c.599C>A p.S200* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV52162094, COSV52162780; called by muse, mutect2, varscan2
- CRYBG1 | c.2946A>T p.R982S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV64812674; called by muse, mutect2, varscan2
- CSMD2 | c.1702T>A p.S568T | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53922093; called by muse, mutect2, varscan2
- CSMD3 | c.6979G>C p.V2327L (on ENST00000297405 / NM_001363185.1; = p.V2223L on NM_052900.3) | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); catalogued as rs766601576, COSV52158186, COSV52209163; called by muse, mutect2, varscan2
- CSMD3 | c.6137C>A p.A2046E (on ENST00000297405 / NM_001363185.1; = p.A1942E on NM_052900.3) | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV52209181; called by muse, mutect2, varscan2
- CSMD3 | c.5279-1G>T p.X1760_splice (on ENST00000297405 / NM_001363185.1; = p.X1656_splice on NM_052900.3) | Splice Site (SNP) | VAF 20/63 reads (32%) | catalogued as COSV52209197; called by muse, mutect2, varscan2
- CYP11B1 | c.880C>A p.L294M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as COSV52828050; called by muse, mutect2, varscan2
- DALRD3 | c.64G>C p.G22R | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV58245368; called by muse, mutect2
- DENND1B | c.1166T>A p.L389Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52466524; called by muse, mutect2, varscan2
- DGKD | c.2580+1G>C p.X860_splice (on ENST00000264057 / NM_152879.3; = p.X816_splice on NM_003648.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/74 reads (15%) | catalogued as COSV51055140; called by muse, mutect2
- DMAC2 | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99700462; called by muse, mutect2
- DOCK4 | c.5666G>T p.G1889V | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV101447925, COSV70238343; called by muse, mutect2
- DOCK4 | c.898C>G p.P300A | Missense Mutation (SNP) | VAF 135/445 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV70322137; called by muse, mutect2, varscan2
- DOT1L | c.1990C>G p.P664A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as COSV67110470; called by muse, mutect2, varscan2
- DSC3 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV64573475; called by muse, varscan2
- DST | c.18359G>T p.C6120F (on ENST00000361203 / NM_001374722.1; = p.C3817F on NM_015548.5) | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55020854; called by muse, mutect2, varscan2
- DTL | c.959A>C p.Y320S | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65342585; called by muse, mutect2
- DUSP15 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.299); catalogued as COSV54066573; called by muse, mutect2, varscan2
- DUSP22 | c.281G>T p.R94M | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60527937; called by muse, mutect2
- EIF3A | c.2210A>T p.Q737L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64961754; called by muse, mutect2, varscan2
- ELAPOR2 | c.1624G>T p.E542* (on ENST00000450689 / NM_001142749.3; = p.E375* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV51885623; called by muse, mutect2
- ELOC | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV53023270; called by muse, mutect2, varscan2
- ELSPBP1 | c.238T>A p.Y80N | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60413948; called by muse, mutect2, varscan2
- EPM2A | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV62298102; called by muse, mutect2, varscan2
- ERBB4 | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV53542273; called by muse, mutect2, varscan2
- ESYT1 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577368857, COSV57274030; called by muse, mutect2, varscan2
- ETV1 | c.1235A>G p.Y412C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54144412; called by muse, mutect2, varscan2
- EVC | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV53833807; called by muse, mutect2, varscan2
- EYA4 | c.1868C>A p.P623H (on ENST00000531901 / NM_001301013.1; = p.P617H on NM_004100.5) | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62054136; called by muse, mutect2, varscan2
- FAM114A2 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV61078106; called by muse, mutect2, varscan2
- FAM149A | c.1381G>A p.V461I (on ENST00000356371 / NM_001367768.2; = p.V170I on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs201494456; called by muse, mutect2, varscan2
- FAM193A | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61190907; called by mutect2, varscan2
- FAM47B | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61454567; called by muse, mutect2, varscan2
- FAM47C | c.2863G>T p.E955* | Nonsense Mutation (SNP) | VAF 53/176 reads (30%) | catalogued as COSV63727370; called by muse, mutect2, varscan2
- FARP1 | c.929T>G p.V310G | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60339867; called by muse, mutect2, varscan2
- FAT4 | c.6127G>T p.D2043Y | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627214, COSV58671970; called by muse, mutect2, varscan2
- FGF23 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.845); catalogued as COSV52976490; called by muse, mutect2, varscan2
- FMN2 | c.4645-1G>T p.X1549_splice | Splice Site (SNP) | VAF 55/141 reads (39%) | catalogued as COSV100144099; called by muse, mutect2, varscan2
- FMN2 | c.4645G>T p.D1549Y | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100144104; called by muse, mutect2, varscan2
- FOSL1 | c.205A>T p.T69S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV100440854; called by muse, mutect2, varscan2
- FREM2 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54841018; called by muse, mutect2, varscan2
- FUNDC2 | c.193T>A p.W65R | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65671114; called by muse, mutect2
- G6PC2 | c.479T>G p.I160S | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56372318; called by muse, mutect2, varscan2
- GAB4 | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs777976157, COSV68754134; called by muse, mutect2, varscan2
- GALNT8 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52898269; called by muse, mutect2, varscan2
- GBP4 | c.1808A>G p.E603G | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63254727; called by muse, mutect2, varscan2
- GFRAL | c.619A>T p.S207C | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61231886; called by muse, mutect2, varscan2
- GLI2 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58044105; called by muse, mutect2, varscan2
- GPATCH2L | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55048991; called by muse, mutect2, varscan2
- GPR158 | c.2872C>A p.P958T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV66268011, COSV66283827; called by muse, mutect2, varscan2
- GPR37 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58257413; called by muse, mutect2, varscan2
- GPR4 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59917341; called by muse, mutect2, varscan2
- GPR83 | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs375569079; called by muse, mutect2, varscan2
- GRIK2 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 108/383 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59743214; called by muse, mutect2, varscan2
- GRIN2B | c.3876G>T p.K1292N | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV74206358; called by muse, mutect2, varscan2
- GYS2 | c.770C>A p.T257K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53924547, COSV53926590; called by muse, mutect2, varscan2
- H4C9 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100574878, COSV62890165; called by muse, mutect2, varscan2
- HAS2 | c.1441G>T p.V481L | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58264767; called by muse, mutect2, varscan2
- HERC5 | c.2134-2A>T p.X712_splice | Splice Site (SNP) | VAF 14/114 reads (12%) | catalogued as COSV52042942, COSV99987523; called by muse, mutect2, varscan2
- HGF | c.209del p.C70Lfs*39 | Frame Shift Del (DEL) | VAF 66/146 reads (45%) | catalogued as COSV55960107; called by mutect2, varscan2
- HIBCH | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs1346343332, COSV62891977; called by muse, mutect2, varscan2
- HOXA1 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56066761; called by muse, mutect2, varscan2
- HOXA3 | c.1139C>A p.P380Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV57827106; called by muse, mutect2, varscan2
- HOXC12 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs754242675, COSV54535250; called by muse, mutect2, varscan2
- HSPB7 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 41/104 reads (39%) | catalogued as COSV58892131; called by muse, mutect2, varscan2
- IGSF1 | c.1019G>T p.S340I | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV63838117; called by muse, mutect2
- IKZF2 | c.696G>C p.Q232H | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.305); catalogued as rs779422250, COSV59578761, COSV59579917; called by muse, mutect2, varscan2
- IL7R | c.1362C>A p.S454R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57409406; called by muse, mutect2, varscan2
- IRS1 | c.745A>C p.M249L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV59337278; called by muse, mutect2, varscan2
- ITSN2 | c.3694G>T p.V1232F | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.24); catalogued as COSV61948726; called by muse, mutect2, varscan2
- JAML | c.245G>T p.G82V (on ENST00000356289 / NM_001098526.2; = p.G72V on NM_153206.3) | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52628055; called by muse, mutect2, varscan2
- KCNT2 | c.2525C>A p.P842H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54085404; called by muse, mutect2, varscan2
- KDM5B | c.3786G>T p.W1262C | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52508975; called by muse, mutect2, varscan2
- KEL | c.50C>A p.A17E | Missense Mutation (SNP) | VAF 78/509 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV62333620, COSV62335743; called by muse, mutect2, varscan2
- KHDC3L | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64869277, COSV64869316; called by muse, mutect2, varscan2
- KIAA0319L | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1049644756, COSV57846713; called by muse, mutect2, varscan2
- KIAA1109 | c.7037C>T p.S2346L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV99150604; called by muse, mutect2, varscan2
- KIF21A | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735382; called by muse, mutect2, varscan2
- KIF2B | c.907G>T p.G303W | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52131680; called by muse, mutect2, varscan2
- KLRK1 | c.381T>A p.C127* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV53698832; called by muse, mutect2, varscan2
- KNSTRN | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs753576982, COSV51106280; called by muse, mutect2
- KRBA1 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1563058597, COSV55441925; called by muse, mutect2, varscan2
- KRT85 | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV57737241; called by muse, mutect2, varscan2
- KRTAP11-1 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60094809; called by muse, mutect2, varscan2
- KRTAP19-2 | c.140G>T p.R47I | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as COSV100477481; called by muse, mutect2, varscan2
- KRTAP19-3 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100477483; called by muse, mutect2, varscan2
- LAMA4 | c.3104G>A p.C1035Y (on ENST00000230538 / NM_001105206.3; = p.C1028Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57898858; called by muse, mutect2, varscan2
- LAMB1 | c.2716C>A p.P906T | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as COSV55966141; called by muse, mutect2, varscan2
- LAX1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs753768323, COSV65848812; called by muse, mutect2, varscan2
- LEPR | c.1542G>T p.R514S | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV60757002; called by muse, mutect2, varscan2
- LPIN2 | c.1318G>T p.G440C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV55240613; called by muse, mutect2, varscan2
- LRP2 | c.6604A>G p.R2202G | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55557980; called by muse, mutect2, varscan2
- LSG1 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54570891; called by muse, mutect2, varscan2
- LTBP1 | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV63189796; called by muse, mutect2, varscan2
- LY9 | c.857C>A p.T286K | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs372475263, COSV99627415; called by muse, varscan2
- LYST | c.3274A>G p.T1092A | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs1377930267, COSV67708206; called by muse, mutect2, varscan2
- MAGEC2 | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 116/263 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV55999762; called by muse, mutect2, varscan2
- MAGED1 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.912); catalogued as rs1557364302, COSV58515569; called by muse, mutect2, varscan2
- MAGED1 | c.1525T>A p.Y509N | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58515583; called by muse, mutect2
- MAP6 | c.1984G>C p.G662R | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV59076217; called by muse, mutect2
- MC3R | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as COSV54763998; called by muse, mutect2, varscan2
- MC3R | c.909C>A p.S303R | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54764005; called by muse, mutect2, varscan2
- MDC1 | c.2568A>T p.K856N | Missense Mutation (SNP) | VAF 112/395 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV64525039; called by muse, mutect2, varscan2
- MDGA1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.987); catalogued as COSV51797204; called by muse, mutect2, varscan2
- MED14 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61357197; called by muse, mutect2, varscan2
- MEIS3 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV58983843; called by muse, mutect2, varscan2
- MICU3 | c.946C>G p.R316G | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.413); catalogued as COSV58846082, COSV58846695; called by muse, mutect2, varscan2
- MMP13 | c.725C>G p.P242R | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52824138, COSV52824346; called by muse, mutect2, varscan2
- MMP9 | c.817A>T p.S273C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63434178; called by muse, mutect2, varscan2
- MS4A14 | c.617C>A p.A206D | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55735578; called by muse, mutect2, varscan2
- MTCL1 | c.1517G>T p.R506M (on ENST00000306329 / NM_001378206.1; = p.R146M on NM_015210.4) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60407214; called by muse, mutect2, varscan2
- MTUS2 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV70916970, COSV70917351; called by muse, mutect2, varscan2
- MUC17 | c.8836A>G p.S2946G | Missense Mutation (SNP) | VAF 74/1369 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs1013103149, COSV60291759; called by muse, mutect2
- MUC5B | c.11134C>G p.P3712A | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs1196763367, COSV71592915; called by muse, mutect2, varscan2
- MXRA5 | c.7372G>T p.G2458W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1411731280, COSV54229833, COSV54236203, COSV54238681; called by muse, mutect2, varscan2
- MYCN | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99808145; called by muse, mutect2, varscan2
- MYH13 | c.3440T>C p.L1147P | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52831975; called by muse, mutect2, varscan2
- MYH6 | c.4748A>T p.E1583V | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62451761; called by muse, mutect2, varscan2
- N4BP2 | c.1664G>T p.R555M | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54703097; called by muse, mutect2, varscan2
- NAALADL2 | c.2279A>T p.E760V | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV71985168; called by muse, mutect2, varscan2
- NAV3 | c.6319G>T p.A2107S (on ENST00000397909 / NM_001024383.2; = p.A2085S on NM_014903.6) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57086517; called by muse, mutect2, varscan2
- NCAPD3 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73198658, COSV73198667; called by muse, mutect2, varscan2
- NCKAP5 | c.2792C>A p.P931H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV58450510, COSV58452261; called by muse, mutect2, varscan2
- NEK1 | c.3026C>T p.P1009L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV71456455; called by muse, mutect2, varscan2
- NEK4 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 80/158 reads (51%) | catalogued as COSV51778682, COSV51780933; called by muse, mutect2, varscan2
- NF1 | c.5493_5494insT p.E1832* (on ENST00000358273 / NM_001042492.3; = p.E1811* on NM_000267.3) | Frame Shift Ins (INS) | VAF 23/141 reads (16%) | catalogued as COSV100646401; called by mutect2, pindel, varscan2
- NLRP14 | c.2885T>A p.L962Q | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55068140; called by muse, mutect2, varscan2
- NLRP3 | c.1872C>A p.S624R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV100276463, COSV60225963; called by muse, mutect2
- NLRP3 | c.1874A>G p.Q625R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as COSV60225976; called by muse, mutect2
- NLRP3 | c.2767G>T p.G923* | Nonsense Mutation (SNP) | VAF 36/97 reads (37%) | catalogued as COSV60220242, COSV60225995; called by muse, mutect2, varscan2
- NOX3 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.628); catalogued as COSV50154227; called by muse, mutect2, varscan2
- NPAS4 | c.355A>T p.I119F | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.209); catalogued as COSV60651002; called by muse, mutect2, varscan2
- NR1H3 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV101269748; called by muse, mutect2, varscan2
- NRCAM | c.3872C>A p.S1291* (on ENST00000379028 / NM_001371124.1; = p.S1170* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 303/425 reads (71%) | catalogued as COSV61039429; called by muse, mutect2, varscan2
- OGDHL | c.1542C>G p.Y514* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV65103075; called by muse, mutect2, varscan2
- OGT | c.2743G>T p.G915C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101035281; called by muse, mutect2
- OLR1 | c.746G>C p.G249A | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV58871839; called by muse, mutect2, varscan2
- OR2T33 | c.800A>T p.N267I | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.752); catalogued as COSV58815786; called by muse, mutect2, varscan2
- OR2T4 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63543460; called by muse, mutect2, varscan2
- OR4L1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV59850263, COSV59851020; called by muse, mutect2, varscan2
- OR51E1 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV67810236; called by muse, mutect2, varscan2
- OR51G2 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148695983, COSV58993480; called by muse, mutect2, varscan2
- OR51V1 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV58315435; called by muse, mutect2, varscan2
- OR5H15 | c.607T>A p.S203T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV62948298; called by muse, mutect2, varscan2
- OR5L1 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs765577071, COSV61734255; called by muse, mutect2, varscan2
- OR5M3 | c.654C>G p.F218L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV56567223; called by muse, mutect2, varscan2
- OR5T1 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 139/333 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100478840; called by muse, mutect2
- OR6T1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.477); catalogued as COSV100189819; called by muse, mutect2, varscan2
- OR8J3 | c.575C>G p.T192S | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV100040564, COSV56881866; called by muse, mutect2, varscan2
- OTC | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.679); catalogued as COSV50002298, COSV99234012; called by muse, mutect2, varscan2
- OTOA | c.2176G>T p.G726C (on ENST00000286149; = p.G712C on NM_144672.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as rs866105290, COSV53756714; called by muse, mutect2, varscan2
- OTOGL | c.6538G>A p.D2180N (on ENST00000547103; = p.D2171N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.464); catalogued as COSV54018130; called by muse, mutect2, varscan2
- OTOP2 | c.1162G>C p.V388L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100508878, COSV58882263; called by muse, mutect2, varscan2
- PARPBP | c.1516A>T p.K506* | Nonsense Mutation (SNP) | VAF 28/40 reads (70%) | catalogued as COSV100268203; called by muse, mutect2, varscan2
- PCLO | c.13307A>G p.H4436R | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356043658, COSV61641549, COSV61648201; called by muse, mutect2
- PCNT | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 18/186 reads (10%) | catalogued as COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2
- PDE4DIP | c.3244G>T p.V1082L | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV57700738; called by muse, mutect2, varscan2
- PDGFRA | c.650A>T p.E217V | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57269462; called by muse, mutect2
- PHKA1 | c.1652G>A p.C551Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.793); catalogued as COSV59807107; called by muse, mutect2, varscan2
- PITX2 | c.749G>A p.S250N (on ENST00000354925 / NM_001204397.1; = p.S257N on NM_000325.6) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV60741271; called by muse, mutect2, varscan2
- PIWIL3 | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59996187; called by muse, mutect2
- PLAC8 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.156); catalogued as COSV100274619, COSV61047519; called by muse, mutect2
- PLCG1 | c.956C>G p.P319R | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.154); catalogued as rs150381500, COSV54819670; called by muse, mutect2, varscan2
- PLCH2 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53944572; called by muse, mutect2, varscan2
- PLEKHB2 | c.58A>T p.K20* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV52176323; called by muse, mutect2, varscan2
- PLIN4 | c.1925C>A p.T642N (on ENST00000301286; = p.T657N on NM_001367868.2) | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV56692851; called by muse, mutect2, varscan2
- PLPPR4 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV64566312, COSV64567911; called by muse, mutect2, varscan2
- PLXNA3 | c.2919C>A p.S973R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100859979, COSV63754431; called by muse, mutect2
- PLXNB2 | c.1877+1G>A p.X626_splice | Splice Site (SNP) | VAF 11/105 reads (10%) | catalogued as COSV63782399; called by muse, mutect2, varscan2
- PMFBP1 | c.1802G>T p.R601M (on ENST00000537465; = p.R596M on NM_031293.3) | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV52825923; called by muse, mutect2, varscan2
- PNLIPRP1 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as COSV62612147; called by muse, mutect2
- POM121L12 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV68693216; called by muse, mutect2, varscan2
- POU3F4 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV64539601; called by muse, mutect2, varscan2
- PPEF1 | c.1142A>G p.Y381C | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV62995975; called by muse, mutect2, varscan2
- PREX2 | c.3894G>T p.M1298I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV55777286; called by muse, mutect2, varscan2
- PRTG | c.2955G>C p.Q985H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); catalogued as COSV66838548; called by muse, mutect2, varscan2
- PTPN2 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV100518439, COSV58997166; called by muse, mutect2, varscan2
- PTPN4 | c.2569G>A p.G857R | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs760486727, COSV55303067; called by muse, mutect2, varscan2
- PTPRN | c.1603G>T p.G535W | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV55349130, COSV55350523; called by muse, mutect2, varscan2
- PYHIN1 | c.753T>G p.H251Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.087); catalogued as COSV63722785; called by muse, mutect2, varscan2
- RAB9B | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 163/346 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV54587776; called by muse, mutect2, varscan2
- RAD17 | c.383A>T p.Q128L (on ENST00000380774 / NM_133339.2; = p.Q117L on NM_002873.1) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99281318; called by muse, mutect2, varscan2
- RAD52 | c.617A>C p.N206T | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV57273196; called by muse, mutect2, varscan2
- RADIL | c.330C>A p.Y110* | Nonsense Mutation (SNP) | VAF 31/84 reads (37%) | catalogued as rs575762308, COSV68201259, COSV68201630; called by muse, mutect2, varscan2
- RAP1GAP | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99264940; called by muse, mutect2, varscan2
- RBFOX1 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.071); catalogued as COSV60962974; called by muse, mutect2, varscan2
- RBM12B | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV66968242; called by muse, mutect2, varscan2
- REM1 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52429544, COSV99147337; called by muse, mutect2
- RGS9 | c.1153C>G p.R385G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52223457, COSV52226295; called by muse, mutect2
- RHOBTB1 | c.1061T>A p.V354E | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61958964; called by muse, mutect2, varscan2
- RIMS2 | c.2924G>A p.G975E (on ENST00000666250 / NM_001348490.2; = p.G783E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.884); catalogued as COSV51690996; called by muse, mutect2, varscan2
- RNF17 | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV55042258; called by muse, mutect2, varscan2
- ROS1 | c.2945A>T p.Y982F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63856527; called by muse, mutect2, varscan2
- RPE65 | c.413C>A p.P138Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.027); catalogued as COSV52016654; called by muse, mutect2, varscan2
- RPGRIP1L | c.3026A>C p.E1009A | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as COSV50908548; called by muse, mutect2, varscan2
- RRP9 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV51754997; called by muse, mutect2, varscan2
- RSAD2 | c.925C>A p.R309S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV101150059, COSV65908443; called by muse, mutect2, varscan2
- RTP2 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV64079124; called by muse, mutect2, varscan2
- RYR3 | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV66783900, COSV66794600, COSV66798915; called by muse, mutect2, varscan2
- SAFB2 | c.2579G>T p.R860L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV53042986, COSV99385817; called by muse, mutect2, varscan2
- SALL1 | c.83C>A p.T28K | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51759225; called by muse, mutect2, varscan2
- SALL4 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.046); catalogued as COSV53853190; called by muse, mutect2, varscan2
- SASH1 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as COSV66562605, COSV66562910; called by muse, mutect2, varscan2
- SASH1 | c.1108G>T p.G370W | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV66562612; called by muse, mutect2, varscan2
- SCARF2 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1431130946, COSV56732525; called by muse, mutect2, varscan2
- SCN7A | c.836T>A p.L279Q | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV69272449; called by muse, mutect2, varscan2
- SDCCAG8 | c.2078G>T p.S693I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.181); catalogued as COSV59410750; called by muse, mutect2, varscan2
- SEC31B | c.2155A>G p.M719V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV64844709; called by muse, mutect2, varscan2
- SEMA3D | c.1883G>T p.R628M | Missense Mutation (SNP) | VAF 141/306 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV52387114, COSV52396097; called by muse, mutect2, varscan2
- SERPINC1 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs767683540, COSV62929657; called by muse, mutect2, varscan2
- SGIP1 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV52771380; called by muse, mutect2, varscan2
- SIM1 | c.2244A>C p.Q748H | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV53493231; called by muse, mutect2, varscan2
- SLC16A1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63709002; called by muse, mutect2
- SLC17A1 | c.646T>A p.W216R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55079562; called by muse, mutect2, varscan2
- SLC22A7 | c.617G>T p.G206V (on ENST00000372585 / NM_153320.2; = p.G204V on NM_006672.3) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65354771; called by muse, mutect2, varscan2
- SLC25A45 | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99587259; called by muse, mutect2, varscan2
- SLC26A2 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99640075; called by muse, mutect2, varscan2
- SLC26A7 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs1366049850, COSV52595768; called by muse, mutect2, varscan2
- SLC2A10 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV63714992; called by muse, mutect2, varscan2
- SLCO1C1 | c.1548T>C p.I516= | Splice Region (SNP) | VAF 19/72 reads (26%) | catalogued as COSV56874189; called by muse, mutect2, varscan2
- SLITRK3 | c.2044C>A p.R682S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV53845401, COSV53849374; called by muse, mutect2, varscan2
- SLK | c.257G>C p.C86S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59826188; called by muse, mutect2, varscan2
- SMARCA4 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV104418413, COSV60797970; called by muse, mutect2, varscan2
- SMARCD2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1457142148, COSV56740002; called by muse, mutect2, varscan2
- SNAP25 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54771619; called by muse, mutect2, varscan2
- SNTB1 | c.584G>C p.R195P | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs769206199, COSV67325027, COSV67327037; called by muse, mutect2, varscan2
- SP100 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV50983561; called by muse, mutect2
- SPECC1 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV54959811; called by muse, mutect2, varscan2
- SPEF2 | c.4384G>T p.G1462C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV57429812, COSV57431497; called by muse, mutect2, varscan2
- SPHKAP | c.1756A>C p.S586R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as COSV60882813; called by muse, mutect2, varscan2
- SPHKAP | c.31A>T p.S11C | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60882824; called by muse, mutect2, varscan2
- SPTA1 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as COSV63749229, COSV63754817; called by muse, mutect2, varscan2
- ST8SIA5 | c.551G>C p.S184T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | PolyPhen benign (0.174); catalogued as COSV59332638; called by muse, mutect2, varscan2
- STAG2 | c.2573T>C p.L858P | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54361671; called by muse, mutect2
- STARD3NL | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as COSV50518634; called by muse, mutect2, varscan2
- STEAP2 | c.1154del p.A385Vfs*2 | Frame Shift Del (DEL) | VAF 44/331 reads (13%) | catalogued as COSV99840811; called by mutect2, pindel*, varscan2
- STIP1 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as COSV59439570; called by muse, mutect2, varscan2
- STK32B | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51492862; called by muse, mutect2, varscan2
- SYCE1 | c.580C>A p.Q194K (on ENST00000343131 / NM_001143764.3; = p.Q158K on NM_130784.3) | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV58217830; called by muse, mutect2, varscan2
- SYT8 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV53288704, COSV99425403; called by muse, mutect2, varscan2
- SYTL2 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs765465082, COSV60360016; called by muse, mutect2, varscan2
- TAS2R42 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as rs137988425; called by muse, mutect2, varscan2
- TBCK | c.1427G>T p.W476L (on ENST00000273980 / NM_001163436.4; = p.W413L on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56757291; called by muse, mutect2, varscan2
- TBK1 | c.969G>C p.K323N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as COSV100538088, COSV59154745; called by muse, mutect2
- TCEAL5 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.229); catalogued as COSV101013108, COSV101013213, COSV65503660; called by muse, mutect2
- TGIF2LX | c.108T>A p.N36K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV52214280; called by muse, mutect2
- TGIF2LX | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs540837899, COSV52214286; called by muse, mutect2
- TIMMDC1 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 81/141 reads (57%) | catalogued as COSV51786950; called by muse, mutect2, varscan2
- TINAG | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV52507401, COSV52516482; called by muse, mutect2, varscan2
- TLR4 | c.1609A>T p.T537S (on ENST00000355622 / NM_138554.5; = p.T497S on NM_003266.4) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV62923514; called by muse, mutect2, varscan2
- TM9SF4 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV54107965, COSV54110547; called by muse, mutect2, varscan2
- TMEM145 | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV52089080; called by muse, mutect2, varscan2
- TMEM94 | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs1214629390, COSV58596843; called by muse, mutect2, varscan2
- TMPRSS9 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs940382148, COSV60228493; called by muse, mutect2, varscan2
- TNR | c.1108C>G p.Q370E | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.045); catalogued as COSV99688581; called by muse, mutect2
- TNS1 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV50711500; called by muse, mutect2, varscan2
- TPR | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV55217440; called by muse, mutect2, varscan2
- TRAM1 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51597570, COSV51598725; called by muse, mutect2, varscan2
- TROAP | c.1638G>T p.E546D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.08); catalogued as COSV57744770; called by muse, mutect2, varscan2
- TSHZ3 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53674250; called by muse, mutect2, varscan2
- TUBA3C | c.1019C>A p.T340N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV68028692; called by muse, mutect2, varscan2
- TUBB8 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59116110; called by muse, mutect2, varscan2
- TYR | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV54478251; called by muse, mutect2, varscan2
- UBC | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60059879; called by muse, varscan2
- UGT2B28 | c.321A>T p.L107F | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100158650; called by muse, mutect2, varscan2
- UGT2B28 | c.322T>C p.Y108H | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100158652; called by muse, mutect2, varscan2
- UGT2B4 | c.1090+1G>C p.X364_splice | Splice Site (SNP) | VAF 12/110 reads (11%) | catalogued as COSV59317930; called by muse, mutect2, varscan2
- UNC13B | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV65935560; called by muse, mutect2, varscan2
- UROC1 | c.1576A>G p.I526V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV52034660; called by muse, mutect2, varscan2
- USP29 | c.237C>A p.N79K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV54240502; called by muse, mutect2, varscan2
- VAX1 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV53329482; called by muse, mutect2, varscan2
- XPNPEP2 | c.492C>A p.D164E | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV64367985; called by muse, mutect2, varscan2
- ZBTB44 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV63537474; called by muse, mutect2, varscan2
- ZC3H6 | c.3157G>T p.D1053Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as COSV59668590; called by muse, mutect2, varscan2
- ZFHX4 | c.4336G>A p.A1446T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761957058, COSV51437596; called by muse, mutect2, varscan2
- ZIC4 | c.294C>A p.Y98* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as COSV67170797, COSV67172343; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1737T>A p.C579* | Nonsense Mutation (SNP) | VAF 31/109 reads (28%) | catalogued as COSV58743132; called by muse, mutect2, varscan2
- ZNF133 | c.41A>T p.E14V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100315356; called by muse, mutect2, varscan2
- ZNF235 | c.1340A>G p.H447R | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs200301700, COSV52157000; called by muse, mutect2, varscan2
- ZNF266 | c.1401G>T p.M467I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV63222364; called by muse, mutect2, varscan2
- ZNF34 | c.1371C>G p.S457R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV100603405, COSV58639933; called by muse, mutect2, varscan2
- ZNF445 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.425); catalogued as COSV68539015; called by muse, mutect2, varscan2
- ZNF461 | c.662G>T p.C221F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV64454029; called by muse, mutect2, varscan2
- ZNF462 | c.1025C>G p.S342C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); catalogued as COSV52942372; called by muse, mutect2, varscan2
- ZNF518B | c.2635C>G p.L879V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV58723037; called by muse, mutect2, varscan2
- ZNF560 | c.712A>T p.R238* | Nonsense Mutation (SNP) | VAF 40/77 reads (52%) | catalogued as COSV56868713; called by muse, mutect2, varscan2
- ZNF638 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as rs192912662, COSV52489441; called by muse, mutect2, varscan2
- ZNF641 | c.785G>T p.R262I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99973421; called by muse, mutect2, varscan2
- ZNF774 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100586260; called by muse, mutect2, varscan2
- ZNF804A | c.2646C>A p.H882Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as COSV56453306; called by muse, mutect2, varscan2
- ZNF831 | c.4880T>C p.V1627A | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1346464822, COSV64041471; called by muse, mutect2, varscan2
- ZSWIM2 | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1559110517, COSV54575102, COSV54576285; called by muse, mutect2, varscan2
- AKR1C8P | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP1B1 | c.1333dup p.R445Pfs*20 | Frame Shift Ins (INS) | VAF 48/122 reads (39%) | called by mutect2, pindel, varscan2
- AP2B1 | c.2739G>T p.T913= | Splice Region (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.1566del p.F523Sfs*8 | Frame Shift Del (DEL) | VAF 46/188 reads (24%) | called by mutect2, pindel, varscan2
- DST | c.1089del p.K364Nfs*7 | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | called by mutect2, pindel, varscan2
- EHD2 | c.1054del p.D352Tfs*12 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- FAM111B | c.1625_1627delinsT p.N542Ifs*39 | Frame Shift Del (DEL) | VAF 36/75 reads (48%) | called by pindel, varscan2*
- GNAZ | c.437del p.E146Gfs*12 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel*
- IGKV1D-17 | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNU1 | c.1952dup p.D652Gfs*24 | Frame Shift Ins (INS) | VAF 46/112 reads (41%) | called by mutect2, varscan2
- MROH8 | c.387del p.G130Efs*9 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- MYO15A | c.5370del p.L1791Cfs*6 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- TRBV2 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- UNC5C | c.2774_2775insGG p.A926Efs*29 | Frame Shift Ins (INS) | VAF 36/139 reads (26%) | called by mutect2, pindel*, varscan2
- ACE2 | c.834G>C p.L278= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as COSV53025503; called by muse, mutect2
- ADAMTSL4 | c.2664G>A p.G888= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs773335343, COSV55001053; called by mutect2, varscan2
- AFF2 | c.510G>T p.L170= | Silent (SNP) | VAF 17/202 reads (8%) | catalogued as COSV60668459; called by muse, mutect2
- AHNAK | c.3060G>T p.V1020= | Silent (SNP) | VAF 59/119 reads (50%) | catalogued as COSV57216841; called by muse, mutect2, varscan2
- AHNAK2 | c.1422C>A p.G474= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV60912297, COSV60918344; called by muse, mutect2, varscan2
- ALAS2 | c.1449A>C p.A483= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV58191429; called by muse, mutect2, varscan2
- ALK | c.1998C>G p.P666= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV101200768, COSV66555521, COSV66572515; called by muse, mutect2, varscan2
- ALK | c.1821C>T p.F607= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV66572521; called by muse, mutect2, varscan2
- AMFR | c.798C>T p.L266= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV51922252; called by muse, mutect2, varscan2
- ANKK1 | c.723C>T p.G241= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV58272415; called by muse, mutect2, varscan2
- ASIC5 | c.27A>G p.V9= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as rs1389236818, COSV72232895; called by muse, mutect2, varscan2
- ATP6V0A4 | c.57G>C p.V19= | Silent (SNP) | VAF 46/328 reads (14%) | catalogued as COSV59476920; called by muse, mutect2, varscan2
- BMP7 | c.799C>A p.R267= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV67781161; called by muse, mutect2, varscan2
- BRDT | c.1113G>A p.T371= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs745926830, COSV62864669; called by muse, mutect2, varscan2
- BSND | c.909C>A p.A303= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV64870785; called by muse, mutect2, varscan2
- C1orf109 | c.192G>T p.R64= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100523544; called by muse, mutect2, varscan2
- C7 | c.606T>C p.N202= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV57475544; called by muse, mutect2, varscan2
- CAPZA3 | c.213C>A p.L71= | Silent (SNP) | VAF 49/143 reads (34%) | catalogued as rs376550649; called by muse, mutect2, varscan2
- CAVIN2 | c.1032C>T p.S344= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs1332181392, COSV58424557; called by muse, mutect2, varscan2
- CDX4 | c.438C>A p.A146= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV65171714; called by muse, mutect2, varscan2
- CHRNA4 | c.861C>G p.V287= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV64719843; called by muse, mutect2, varscan2
- CLEC9A | c.678G>T p.T226= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as COSV100191269; called by muse, mutect2, varscan2
- CLK1 | c.315T>C p.S105= | Silent (SNP) | VAF 54/181 reads (30%) | catalogued as rs891441284, COSV58432857; called by muse, mutect2, varscan2
- CNTN2 | c.2028C>T p.T676= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100084814; called by muse, mutect2
- CNTNAP4 | c.1107T>A p.S369= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV56685356; called by muse, mutect2, varscan2
- DCAF12L2 | c.147C>T p.R49= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV63582235; called by muse, mutect2, varscan2
- DLGAP3 | c.1140C>A p.T380= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV52394832; called by muse, mutect2, varscan2
- DMD | c.9009C>A p.T3003= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as CD165364, COSV58919281; called by muse, mutect2
- DNAH10 | c.9795G>T p.S3265= (on ENST00000409039; = p.S3204= on NM_207437.3) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV68995408; called by muse, mutect2
- DNAH11 | c.3825A>C p.A1275= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV60960861; called by muse, mutect2, varscan2
- DOP1A | c.903C>T p.I301= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV52711858; called by muse, mutect2
- DRD3 | c.507G>C p.L169= | Silent (SNP) | VAF 57/126 reads (45%) | catalogued as COSV55680728; called by muse, mutect2, varscan2
- DST | c.21909A>T p.S7303= (on ENST00000361203 / NM_001374722.1; = p.S4976= on NM_015548.5) | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV55020839; called by muse, mutect2, varscan2
- EFCAB3 | c.795G>A p.E265= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV59502639, COSV59505108; called by muse, mutect2, varscan2
- EPHB6 | c.2436G>T p.V812= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as COSV63892138; called by muse, mutect2, varscan2
- ESRRG | c.801A>T p.T267= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV63165396; called by muse, mutect2
- F9 | c.1038C>G p.L346= | Silent (SNP) | VAF 69/229 reads (30%) | catalogued as COSV54380853; called by muse, mutect2, varscan2
- FAM183A | c.156C>T p.P52= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100088250, COSV58921634; called by muse, mutect2, varscan2
- FAM90A1 | c.105C>A p.P35= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV56712732; called by muse, mutect2, varscan2
- FANCM | c.3753T>C p.D1251= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs748733630, COSV57502314; called by muse, mutect2, varscan2
- FBN3 | c.8169C>T p.I2723= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV53664436; called by muse, mutect2, varscan2
- FERD3L | c.114C>A p.S38= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV51762306; called by muse, mutect2, varscan2
- GABRE | c.1401C>T p.T467= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV64820000; called by muse, mutect2
- GABRG1 | c.168C>A p.A56= | Silent (SNP) | VAF 63/229 reads (28%) | catalogued as COSV54955990; called by muse, mutect2, varscan2
- GLI2 | c.54G>T p.G18= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as COSV58044099; called by muse, mutect2, varscan2
- GML | c.417G>T p.L139= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV55277551; called by muse, mutect2, varscan2
- GPR142 | c.1080G>T p.L360= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs746882765, COSV59519641; called by muse, mutect2, varscan2
- GPR153 | c.732C>T p.G244= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100928489; called by muse, mutect2, varscan2
- GRIA2 | c.1860C>A p.R620= | Silent (SNP) | VAF 27/182 reads (15%) | catalogued as COSV52394066; called by muse, mutect2, varscan2
- GRID1 | c.2337C>A p.P779= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV60034094; called by muse, mutect2, varscan2
- GRIN3A | c.2067C>T p.A689= | Silent (SNP) | VAF 68/136 reads (50%) | catalogued as rs757749435, COSV100701412, COSV62454933; called by muse, mutect2, varscan2
- H2AC12 | c.360G>A p.K120= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs766851091, COSV63617147; called by muse, mutect2, varscan2
- HOXA3 | c.729C>A p.R243= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV57827116; called by muse, mutect2, varscan2
- HOXC10 | c.549C>A p.R183= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100329051; called by muse, mutect2, varscan2
- HTR2A | c.1032C>A p.I344= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV101096636; called by muse, mutect2
- IBSP | c.384T>A p.A128= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV56896103, COSV99883346; called by muse, mutect2, varscan2
- INTS6L | c.471A>T p.L157= | Silent (SNP) | VAF 95/198 reads (48%) | catalogued as COSV66084700; called by muse, mutect2, varscan2
- IQCF3 | c.232C>A p.R78= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV101469663, COSV101469670, COSV71309616; called by muse, mutect2, varscan2
- IRS4 | c.1068C>A p.S356= | Silent (SNP) | VAF 16/242 reads (7%) | catalogued as COSV64533196, COSV64534267; called by muse, mutect2
- JAKMIP3 | c.408G>C p.L136= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs1330705391, COSV53824504; called by muse, mutect2, varscan2
- JPH3 | c.855C>A p.T285= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV52468869, COSV99414189; called by muse, mutect2, varscan2
- KCNA6 | c.1134G>T p.L378= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs776663725, COSV54975878; called by muse, mutect2, varscan2
- KIAA0100 | c.1413C>T p.C471= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV66493832; called by muse, mutect2, varscan2
- KIF2B | c.573C>A p.I191= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV52131671; called by muse, mutect2, varscan2
- LAMA1 | c.9009A>G p.P3003= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs1274296818, COSV67538904; called by muse, mutect2, varscan2
- LRP1B | c.4395T>A p.G1465= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV67233636; called by muse, mutect2, varscan2
- LUZP2 | c.753G>T p.A251= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV61207692; called by muse, mutect2, varscan2
- MDN1 | c.1137A>T p.G379= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV65523218; called by muse, mutect2, varscan2
- MUC5B | c.7374C>G p.T2458= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs773325923, COSV101500171; called by muse, mutect2, varscan2
- MYO7B | c.1794A>G p.A598= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV67348596; called by muse, mutect2, varscan2
- NEUROD1 | c.102C>T p.H34= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs748626988, COSV99716854, COSV99717080; called by muse, mutect2, varscan2
- NLGN1 | c.192G>T p.G64= | Silent (SNP) | VAF 92/160 reads (58%) | catalogued as COSV64336714; called by muse, mutect2, varscan2
- NLGN4X | c.2034C>A p.T678= | Silent (SNP) | VAF 45/171 reads (26%) | catalogued as COSV52009219; called by muse, mutect2, varscan2
- NPAP1 | c.582C>A p.T194= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV61508054; called by muse, varscan2
- NPAS4 | c.285C>G p.L95= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV60650804, COSV60650993; called by muse, mutect2, varscan2
- OLFML2B | c.1920C>A p.G640= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV54197162; called by muse, mutect2, varscan2
- OPN5 | c.162C>T p.V54= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV55245960; called by muse, mutect2, varscan2
- OR13C9 | c.441G>C p.G147= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV52242389; called by muse, mutect2, varscan2
- OR13F1 | c.312C>T p.S104= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV58251794; called by muse, mutect2, varscan2
- OR2AK2 | c.99C>A p.T33= | Silent (SNP) | VAF 26/304 reads (9%) | catalogued as COSV63554593; called by muse, mutect2
- OR4A16 | c.36C>A p.L12= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV59043584; called by muse, mutect2, varscan2
- OR4P4 | c.273C>A p.S91= | Silent (SNP) | VAF 103/233 reads (44%) | catalogued as COSV58922393; called by muse, mutect2, varscan2
- OR51D1 | c.948C>A p.L316= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV62914332; called by muse, mutect2, varscan2
- OR51F2 | c.96T>A p.P32= | Silent (SNP) | VAF 106/254 reads (42%) | catalogued as COSV59065036; called by muse, mutect2, varscan2
- OR51F2 | c.735C>A p.S245= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100437935, COSV59065047; called by muse, mutect2, varscan2
- OR52L1 | c.267G>T p.L89= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100176081, COSV59987738; called by muse, mutect2, varscan2
- OR5T1 | c.663C>G p.V221= | Silent (SNP) | VAF 60/276 reads (22%) | catalogued as COSV100478843, COSV57303452, COSV57304714; called by muse, mutect2, varscan2
- OR6C1 | c.660C>A p.I220= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV65573684; called by muse, mutect2, varscan2
- OXA1L | c.609C>T p.A203= (on ENST00000285848; = p.A143= on NM_005015.5) | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV53537412; called by muse, mutect2, varscan2
- PAX6 | c.1188C>A p.L396= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs776244636, COSV53794020; called by muse, mutect2, varscan2
- PDE2A | c.2049C>T p.D683= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV57808819; called by muse, mutect2, varscan2
- PLXNA4 | c.1623G>T p.R541= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV58133904; called by muse, mutect2, varscan2
- POU3F4 | c.294G>A p.S98= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV64539589; called by muse, mutect2, varscan2
- PRMT1 | c.930G>T p.T310= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV60194556, COSV60195974; called by muse, mutect2, varscan2
- PRTG | c.1941T>A p.A647= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV66838553; called by muse, mutect2, varscan2
- PSME4 | c.4578A>T p.I1526= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV66365663; called by muse, mutect2, varscan2
- PTCHD4 | c.2433C>T p.P811= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV59787567; called by muse, mutect2, varscan2
- PTPRT | c.2859A>T p.R953= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV61989406; called by muse, mutect2, varscan2
- QSER1 | c.3162A>T p.A1054= (on ENST00000399302; = p.A1183= on NM_001076786.3) | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV67900892; called by muse, mutect2, varscan2
- REM1 | c.78G>T p.R26= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99146918; called by muse, mutect2
- RSPO1 | c.258C>A p.A86= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV62974475; called by muse, mutect2, varscan2
- RYR2 | c.11886C>A p.S3962= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV63691170; called by muse, mutect2, varscan2
- SEZ6 | c.840C>T p.G280= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV57981129; called by muse, mutect2, varscan2
- SIM1 | c.1995C>A p.R665= | Silent (SNP) | VAF 76/251 reads (30%) | catalogued as COSV53493237; called by muse, mutect2, varscan2
- SLC15A3 | c.702G>T p.V234= | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as COSV57172089; called by muse, mutect2, varscan2
- SLC20A1 | c.1575T>C p.F525= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as COSV55611737; called by muse, mutect2, varscan2
- SPTAN1 | c.3228G>T p.L1076= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV63987820; called by muse, mutect2, varscan2
- SSH1 | c.1464G>T p.P488= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV58457113; called by muse, mutect2, varscan2
- SSTR1 | c.573C>A p.P191= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99942788, COSV99943253; called by muse, mutect2, varscan2
- SYNE1 | c.17409G>A p.K5803= (on ENST00000367255 / NM_182961.4; = p.K5732= on NM_033071.3) | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as COSV55008636; called by muse, mutect2, varscan2
- SYNE1 | c.12489G>A p.L4163= (on ENST00000367255 / NM_182961.4; = p.L4092= on NM_033071.3) | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as rs200926166, COSV55008673; called by muse, mutect2, varscan2
- TENM1 | c.7554C>G p.V2518= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as COSV64434441, COSV64442720; called by muse, mutect2
- THSD7B | c.2907C>A p.A969= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV55699011; called by muse, mutect2, varscan2
- TM7SF2 | c.741C>T p.T247= | Silent (SNP) | VAF 78/248 reads (31%) | catalogued as COSV54207897; called by muse, mutect2, varscan2
- TMEM121 | c.249C>T p.I83= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101180053; called by muse, mutect2, varscan2
- TMEM161B | c.552A>T p.A184= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV56931552; called by muse, mutect2, varscan2
- TPTE | c.1428G>C p.V476= (on ENST00000618007 / NM_199261.4; = p.V458= on NM_199259.4) | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- TRHR | c.1002C>T p.L334= | Silent (SNP) | VAF 70/228 reads (31%) | catalogued as COSV61234782; called by muse, mutect2, varscan2
- TXLNB | c.1674C>A p.P558= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV64444387; called by muse, mutect2, varscan2
- TYR | c.789C>A p.L263= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV54478240; called by muse, mutect2, varscan2
- TYRO3 | c.1791C>T p.P597= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV55484034, COSV55485601; called by muse, mutect2
- UNC13A | c.2577G>A p.Q859= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV53198572; called by muse, mutect2, varscan2
- VPS13B | c.2314C>T p.L772= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV62021057; called by muse, mutect2, varscan2
- XKRX | c.210C>G p.T70= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV60708480; called by muse, mutect2, varscan2
- ZER1 | c.1920C>T p.H640= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV52566391; called by muse, mutect2, varscan2
- ZFC3H1 | c.2904G>T p.R968= | Silent (SNP) | VAF 54/97 reads (56%) | catalogued as COSV66433533; called by muse, mutect2, varscan2
- ZP4 | c.1284A>T p.T428= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV63912355; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148293 G>A | 5'Flank (SNP) | VAF 11/61 reads (18%) | catalogued as rs375682246; called by muse, mutect2, varscan2
- ANK1 | c.5619+307G>T | Intron (SNP) | VAF 24/136 reads (18%) | catalogued as COSV99224570; called by muse, mutect2, varscan2
- CIT | c.2082+1983C>G | Intron (SNP) | VAF 19/126 reads (15%) | catalogued as COSV99948940; called by muse, mutect2, varscan2
- CNOT1 | c.3523-927G>T | Intron (SNP) | VAF 28/96 reads (29%) | catalogued as COSV99799628; called by muse, mutect2
- CNOT1 | c.3523-929A>T | Intron (SNP) | VAF 28/95 reads (29%) | catalogued as COSV99799632; called by muse, mutect2
- COL25A1 | c.1845+26C>T | Intron (SNP) | VAF 15/76 reads (20%) | catalogued as rs754794296, COSV101211281, COSV67652775; called by muse, mutect2, varscan2
- EDA | c.396+4219C>T | Intron (SNP) | VAF 20/44 reads (45%) | catalogued as rs1177591547, COSV100140793; called by muse, mutect2, varscan2
- FOLH1B | n.1458C>A | RNA (SNP) | VAF 75/270 reads (28%) | catalogued as rs556079298; called by muse, mutect2, varscan2
- GNAO1 | c.723+7072G>T | Intron (SNP) | VAF 21/62 reads (34%) | catalogued as COSV52615642; called by muse, mutect2, varscan2
- GRM1 | c.2661-7268A>G | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as rs1468269369, COSV99265074; called by muse, mutect2, varscan2
- IGLL5 | chr22:22899653 T>C | 3'Flank (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- KRT18P23 | chr22:44571483 G>A | 3'Flank (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- PIK3R6 | c.-195G>T | 5'UTR (SNP) | VAF 13/32 reads (41%) | catalogued as COSV61003671; called by muse, mutect2, varscan2
- SLC35E2A | n.1018G>T | RNA (SNP) | VAF 11/80 reads (14%) | catalogued as rs746289642; called by muse, mutect2, varscan2
- SLC66A1L | n.193A>T | RNA (SNP) | VAF 18/21 reads (86%) | catalogued as COSV100396400; called by muse, mutect2, varscan2
- TAF9B | c.-1C>G | 5'UTR (SNP) | VAF 14/204 reads (7%) | catalogued as rs782700437, COSV100540611; called by muse, mutect2
- TET2 | c.3409+68G>T | Intron (SNP) | VAF 5/49 reads (10%) | catalogued as COSV99481928; called by muse, mutect2, varscan2
- ZHX2 | c.-1C>T | 5'UTR (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100072771; called by muse, mutect2
